Surgical pathology report (de-identified scan), TCGA case TCGA-LA-A446, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Candler, specimen TCGA-LA-A446-01A (Primary Tumor).

[page 1 of 6]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

Specimen Inquiry

PAGE 1

PATIENT: [REDACTED]
REG DR: [REDACTED]

ACCT #: [REDACTED]
AGE/SX: [REDACTED]
DOB: [REDACTED]
STATUS: [REDACTED]

LOC: [REDACTED]
ROOM: [REDACTED]
BED: [REDACTED]
TLOC: [REDACTED]

U #: [REDACTED]
REG: [REDACTED]
DIS: [REDACTED]

SPEC #: [REDACTED] RECD: [REDACTED] STATUS: [REDACTED] PERFORMED AT [REDACTED]
COLL: [REDACTED] TIME IN FORMALIN: [REDACTED]

CLINICAL INFORMATION:

Pre-Op Diagnosis: Lung CA

Remarks:

- Specimen(s):
- A. R4 lymph node
- B. Level 7 lymph node
- C. Right upper lobe wedge
- D. 4L lymph node
- E. Level 9 lymph node
- F. Additional level 7 lymph node
- G. Level 10 lymph node
- H. Level 9 lymph node
- I. Right lower lobe (lung)
- J. Right middle lobe
- K. Level 10 lymph node
- L. Level 10 lymph node
- M. Level 10 lymph node

MICROSCOPIC DIAGNOSIS

- A. R4 LYMPH NODE:
- REACTIVE LYMPH NODE
- B. L7 LYMPH NODE:
- REACTIVE LYMPH NODE
- C. RIGHT UPPER LOBE WEDGE RESECTION:
- SCAR AND CHRONIC INFLAMMATORY CHANGES
- FIBROUS PLEURAL ADHESIONS, SEE DESCRIPTION
- D. 4L LYMPH NODE:
- REACTIVE LYMPH NODE
- E. LEVEL 7 LYMPH NODE:
- REACTIVE LYMPH NODE
- F. LEVEL 7 LYMPH NODE:
- REACTIVE LYMPH NODE
- G. LEVEL 10 LYMPH NODE:
- LUNG PARENCHYMA WITH FIBROUS ADHESIONS
- LYMPH NODE NOT IDENTIFIED
- H. LEVEL 9 LYMPH NODE:

1CD0-3
carcinoma, squamous
cell, NOS
8070/3
Site: lung, lower lobe
C34.3
8/23/12
RD

** CONTINUED ON NEXT PAGE **

[page 2 of 6]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

PAGE 2

PCI [REDACTED]

SPEC #:

PATIENT: [REDACTED]

(Continued)

MICROSCOPIC DIAGNOSIS

(Continued)

- REACTIVE LYMPH NODE

I. RIGHT LOWER LOBE:

- SQUAMOUS CELL CARCINOMA
- SEE COMMENT FOR DETAILS

J. RIGHT MIDDLE LOBE:

- SQUAMOUS CELL CARCINOMA IN SITU AT BRONCHIAL MARGIN
- REACTIVE LYMPH NODES
- EMPHYSEMATOUS CHANGES

K. LEVEL 10 LYMPH NODE:

- REACTIVE LYMPH NODE

L. LEVEL 10 LYMPH NODE:

- REACTIVE LYMPH NODE

M. LEVEL 10 LYMPH NODE:

- PULMONARY PARENCHYMAL TISSUE
- LYMPH NODE NOT IDENTIFIED

COMMENT(S)

PROTOCOL FOR THE EXAMINATION OF SPECIMENS WITH PRIMARY NON-SMALL CELL CARCINOMA OF THE LUNG
BASED ON AJCC/UICC TNM, 7TH EDITION:

LUNG:	Resection
SPECIMEN:	Lobes of lung, lower and middle
	Wedge resection of upper lobe
PROCEDURE:	Wedge resection and lobectomies
SPECIMEN INTEGRITY:	Intact
SPECIMEN LATERALITY:	Right
TUMOR SITE:	Lower lobe
TUMOR SIZE:	2.8 cm
TUMOR FOCALITY:	Unifocal
HISTOLOGIC TYPE:	Squamous cell carcinoma
HISTOLOGIC GRADE:	G2: Moderately differentiated
VISCERAL PLEURAL INVASION:	Not identified
TUMOR EXTENSION:	Not applicable
MARGINS:	All margins uninvolved by invasive carcinoma
	- Distance of invasive carcinoma from closest margin: 1.1 cm
	Bronchial Margin: Uninvolved by invasive carcinoma
	Bronchial Margin: Involved by carcinoma in situ
	Vascular Margin: Uninvolved by invasive carcinoma
	Parenchymal Margin: Not applicable

** CONTINUED ON NEXT PAGE **

[page 3 of 6]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

PAGE 3

SPEC #: [REDACTED] PATIENT: [REDACTED] (Continued)

COMMENT(S)

(Continued)

	Parietal/Pleural Margin: Not applicable
	Chest Wall Margin: Not applicable
TREATMENT EFFECT:	Not applicable
LYMPH-VASCULAR INVASION:	Indeterminate
PATHOLOGIC STAGING:	Primary Tumor: pT1b
	Regional Lymph Nodes: pN0
	Number of Lymph Nodes Examined: 10
	Number of Lymph Nodes Involved: 0
	Distance Metastasis: Not applicable
ADDITIONAL PATHOLOGIC FINDINGS:	Emphysematous changes

GROSS DESCRIPTION:

Specimens A and B are received in the non-fixed state in the operating room.

A is labeled "R4 lymph node". The multiple red-black fragments of tissue aggregate to 0.8 cm, entirely frozen in block A.

B is labeled "level 7 lymph node". The two reddish fragments of tissue aggregate to 0.5 cm, entirely frozen in block B.

C. Received in the unfixed state in the operating room labeled with the patient's name and "~~right upper lobe wedge~~" is a single granular wedge of lung measuring 6.3 x 2.5 x 2.2 cm. Adhesions are present on the pleural surface. Staple line is removed. Cross sections demonstrate a grayish-yellow stellate area measuring about 1.2 x 0.8 x 0.8 cm. A representative piece is frozen along with a smear imprint.

D. Labeled "4L lymph node" is a single 0.4 cm brownish node, entirely submitted in cassette D.

E. Labeled "level 7 lymph node" is a 0.8 cm irregular, yellowish-black piece of tissue, entirely submitted in block E for permanent section.

Four additional parts are received. The first three parts are received in formalin labeled with the patient's name.

F. Labeled "additional level 7 lymph node" is a 1.6 x 1.5 x 1.0 cm focally disrupted anthracotic, gray-black lymph node. The node is bisected and entirely submitted in cassette F1.

G. Labeled "level 10 lymph node" is a 1.4 x 1.0 x 0.8 cm nodular, purple-red to black anthracotic portion of tissue. The tissue is trisected to be consistent with lung parenchyma, entirely submitted in cassette G1.

H. Labeled "level 9" is a 0.7 x 0.5 x 0.4 cm tissue biopsy. The biopsy is bisected to have a somewhat cystic appearance with associated yellow adipose, entirely submitted in cassette H1.

** CONTINUED ON NEXT PAGE **

[page 4 of 6]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

PAGE 4

SPEC #:

PATIENT:

(Continued)

GROSS DESCRIPTION: (Continued)

I. Received fresh for frozen section and for tissue banking designated "right lower lobe" is a 270 gram, 18.0 x 11.0 x 3.5 cm lobe of lung. The staples are removed from the bronchial margin, and the bronchial margin is sectioned to be submitted for frozen section diagnosis. The pleural surface has a mottled purple, congested to pink-tan and spongy appearance. There is scant anthracotic marbling. The lung is sectioned to have a 2.8 x 2.6 x 2.5 cm indurated, nodular tumor mass. The tumor mass is centrally located and comes to within 1.1 cm of the bronchial margin. The mass focally obliterates the bronchus and surrounds the vasculature. The tumor does not involve the pleural and comes to within 0.3 cm of the pleural surface. The remainder of the lung is sectioned to have a red-brown to tan-brown, focally, peripherally spongy appearance. No additional lesions are identified. There are scant hilar lymph nodes present on the specimen. A portion of tumor is selected for tissue banking. Representative sections are sampled as labeled:

- I1 - frozen section residue (bronchial margin)
- I2 - vascular margins and hilar lymph nodes
- I3-I6 - sections of tumor to bronchus perpendicular to sections submitted for frozen section diagnosis (to include obliterated bronchus and surrounding vessels)
- I7-I9 - sections of tumor to normal parenchyma and nearest pleura
- I10 - sections from superior aspect of lower lobe
- I11 - sections from mid aspect of lower lobe adjacent to tumor
- I12 - sections of inferior lower lobe sampled

J. Part 10, received fresh for frozen section diagnosis and labeled "right middle lobe", is a partially inflated 82 gram, 12.0 x 9.0 x 2.5 cm middle lobe of right lung. The lobe of the lung has a separate, diffusely stapled 4.0 x 3.0 x 2.0-cm area of parenchyma with a 2.0-cm bronchial stem. The staples are removed and the bronchial margin is submitted for frozen section diagnosis. The staples are removed from the area from where the lower lobe bronchus inserts. There is focal anthracotic lymphoid tissue surrounding the bronchus. The lateral surface of the middle lobe has a purple mildly congested appearance with a peripheral pink-tan spongy appearance. There is a focal area of possible cauterized adhesions on the surface of the middle lobe. The middle lobe is sectioned to have a pink-tan to yellow-brown spongy appearance. No tumor-like masses or lesions are identified. There is a focal area of congestion at one pole. Representative sections are sampled from across the lobe to include perpendicular sections down the bronchus with the proximal previously removed margin inked blue as labeled:

- J1 - bronchial margin frozen section residue
- J2 - bronchial margin from lower lobe insertion and hilar lymph nodes
- J3,J4 - perpendicular sections along middle lobe bronchus
- J5 - described pleural adhesions
- J6,J7 - sections of middle lobe parenchyma from a cross specimen.

Specimens K, L and M are submitted in formalin containers labeled with the patient's name.

K is labeled "level 10 lymph node". The irregularly shaped blackish-red piece of tissue measures 0.8 cm, entirely submitted in cassette K.

L is labeled "level 10 lymph node". The single reddish-black 0.6 cm piece of tissue is entirely submitted in cassette L.

** CONTINUED ON NEXT PAGE **

[page 5 of 6]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

PAGE 5

SPEC # [REDACTED]

PATIENT: [REDACTED]

(Continued)

GROSS DESCRIPTION: (Continued)

M is labeled "level 10 lymph node". The specimen consists of an irregular, triangular piece of tissue. Multiple staples are present in it. The specimen measures 1.6 cm. A lymph node is not grossly identified. The tissues are fairly well macerated by the time I removed the sutures to get enough tissue for submission for histology. These pieces are submitted in cassette M.

MICROSCOPIC DESCRIPTION:

C: The fibrous adhesion on the wedge of the upper lobe demonstrates chronic fibrous adhesions associated with fibroadipose vascular connective tissue and a large nerve.

INTRAOPERATIVE CONSULTATION:

A. FROZEN SECTION DIAGNOSIS R4 LYMPH NODE:

- REACTIVE LYMPH NODE

B. FROZEN SECTION DIAGNOSIS LEVEL 7 LYMPH NODE:

- REACTIVE LYMPH NODE

C. FROZEN SECTION DIAGNOSIS AND CYTOLOGY SMEARS RIGHT UPPER LOBE WEDGE:

- SCAR AND CHRONIC INFLAMMATION
- PLEURAL ADHESIONS
- NO EVIDENCE OF MALIGNANCY

I. FROZEN SECTION, RIGHT LOWER LOBE:

- SQUAMOUS CELL CARCINOMA IN SITU PRESENT AT BRONCHIAL MARGIN

J. FROZEN SECTION, RIGHT MIDDLE LOBE:

- SQUAMOUS CELL CARCINOMA IN SITU AT MARGIN
- FINDINGS DISCUSSED WITH

PHOTO DOCUMENTATION

** CONTINUED ON NEXT PAGE **

[page 6 of 6]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

PAGE 6

SPEC #:

PATIENT:

(Continued)

PHOTO DOCUMENTATION

(Continued)

Signed ____ (signature on file) ____

** END OF REPORT **

Source: NCI Genomic Data Commons file 399ec74c-5121-4d38-81de-e51d9a097f38 (TCGA-LA-A446.45894ED8-CCB0-4FD7-8A28-DAFBA3C645AE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).